Somatic mutation profile of tumor specimen TCGA-DJ-A3VL-01A (aliquot TCGA-DJ-A3VL-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.9 years (14,219 days).
Specimen TCGA-DJ-A3VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e896a40-ca6c-4a1f-b0cc-95234c6a46fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VL-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VL-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e915544e-f426-4985-bef0-9c5c786771aa

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NTSR2 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV60992161; called by muse, mutect2, varscan2
- OGFOD2 | c.908T>G p.L303R (on ENST00000228922 / NM_001304833.1; = p.L243R on NM_024623.3) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54905647; called by muse, mutect2, varscan2
- RASA1 | c.2624G>C p.G875A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.599); catalogued as COSV57195978, COSV57199541; called by muse, mutect2, varscan2
- BRAF | c.1587_1601del p.P530_Q534del (on ENST00000288602 / NM_001374244.1; = p.P490_Q494del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- CYP4F11 | c.1527G>A p.E509= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV56128697; called by muse, mutect2
